Gene-level copy-number profile of tumor specimen TCGA-P3-A6T5-01A from TCGA case TCGA-P3-A6T5, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower gum; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 79.3 years (28,977 days).
Specimen TCGA-P3-A6T5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.32aee47e-fa3c-4c75-8817-22199af8f249.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P3-A6T5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c3fa9c99-53d1-450b-ba66-46af85b79374

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 2; copy number 2: 3,472; copy number 3: 17,143; copy number 4: 17,241; copy number 5: 7,330; copy number 6: 8,051; copy number 7: 3,762; copy number 8: 1,800; copy number 9: 837; copy number 10: 111; copy number 11: 48; copy number 18: 3; copy number 26: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P3-A6T5-01A-11D-A34I-01): tumor purity 0.42, ploidy 4.31, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–22,128,103, 7 genes (within-gene range 0–9): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,005 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–22,029,594, 314 genes, copy number 9 (within-gene range 0–9) (broad region; genes not listed).
- chr9:22,117,665–43,045,120, 455 genes, copy number 9 (broad region; genes not listed).
- chr11:63,369,785–64,723,197, 68 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr11:71,787,510–72,674,591, 49 genes, copy number 10 (within-gene range 6–10): FAM86C1P, ALG1L9P, ZNF705E, DEFB108B, RNA5SP342, DEFB130C, AP002495.1, DEFB131B, OR7E128P, OR7E126P, RNF121, AP002490.2, IL18BP, NUMA1, AP002490.1, RNU6-72P, MIR3165, AP000812.4, LRTOMT, LAMTOR1, AP000812.3, ANAPC15, FOLR3, RPEP6, FOLR1P1, AP000812.1, AP000812.2, FOLR1, FOLR2, INPPL1, PHOX2A, AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1.
- chr11:78,015,715–79,989,630, 30 genes, copy number 11–26: AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1.
- chr11:85,916,502–86,952,910, 27 genes, copy number 11 (within-gene range 6–11): AP003128.1, SLC25A1P1, PICALM, RNU6-560P, LINC02695, FNTAP1, Metazoa_SRP, EED, MIR6755, AP003084.1, SETP17, HIKESHI, RN7SL225P, CCDC81, AP001831.1, PTP4A1P6, AP001148.1, ME3, AP003059.1, AP003059.2, PRSS23, MOB4P2, OR7E13P, AP000654.1, OR7E2P, AP001528.1, AP001528.2.
- chr11:93,726,654–94,114,208, 20 genes, copy number 10 (within-gene range 6–10): AP001273.1, TAF1D, SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40, C11orf54, AP001273.2, MED17, VSTM5, Y_RNA, AP002795.1, HPRT1P3, HEPHL1, PHBP16.
- chr11:103,675,994–107,018,476, 42 genes, copy number 10 (within-gene range 6–10): AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552, AP001485.1, AP002004.1, CASP12, CASP4LP, CASP4, AP001153.1, CASP5, CASP1, CARD16, AP001153.2, CASP1P2, CARD17, CASP1P1, CARD18, OR2AL1P, AP003181.1, Metazoa_SRP, GRIA4, HSPD1P13, RNU4-55P, RNU6-277P, AP000813.1, MSANTD4, KBTBD3, AASDHPPT, AP001001.1, AP001001.2, LINC02719, AP002001.3, AP002001.1, AP002001.2, AP003173.1, GUCY1A2, AP001282.2, AP001282.1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
